Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4904, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4904-01A (Primary Tumor).

Surgery Date: [REDACTED]

TCGA-CJ-4904

Pathology Report

DIAGNOSIS

- (A) LEFT KIDNEY AND ADRENAL:
RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN NUCLEAR GRADE 3.
TUMOR MEASURES 14.5 CM IN MAXIMUM DIMENSION.
LYMPHOVASCULAR INVASION PRESENT. (SEE COMMENT)
Resection margins, free of tumor.
Adrenal gland, no tumor identified.
- (B) PERIAORTIC LYMPH NODE, LEFT:
Four lymph nodes, no tumor present.
- (C) GASTROINTESTINAL PREAORTIC LYMPH NODES:
Five lymph nodes, no tumor present.
- (D) SUPRAHILAR LYMPH NODE:
Four lymph nodes, no tumor present.
- (E) MECKEL'S DIVERTICULUM:
Meckel's diverticulum with enterolith.
Two microscopic foci of carcinoid tumor. (See comment)

COMMENT

The tumor in the left kidney (specimen A) involves a medium caliber muscle containing segmental vessel within the renal sinus.

The Meckel's diverticulum specimen (E) contains two microscopic foci of carcinoid tumor within the small intestinal submucosa (1.5 mm) and subserosa (less than 0.5 mm).

GROSS DESCRIPTION

(A) LEFT KIDNEY AND ADRENAL - A left kidney and adrenal, overall 20.0 x 15.0 x 7.5 cm, composed of kidney with tumor (18 x 15 x 6.0), segment of ureter (7.0 x 0.5 cm), adrenal gland (5.0 x 2.5 x 0.5 cm) is cut open to reveal a 14.5 x 10.0 x 7.0 cm mass. Cut surface is heterogeneous with extensive necrotic, hemorrhagic and pale green translucent myxoid areas. The tumor grossly appears to involve the renal sinus and a tumor nodule is seen inside a sinus vessel. The tumor infiltrates through the entire thickness of the kidney and appears to be confined within the organ; however, focally, the surface of the kidney tumor is within 3.0 mm from the surface of Gerota's fascia.

The adrenal gland is grossly unremarkable.

A fragment of tissue is submitted for electron microscopy. Additional tissue and normal kidney are submitted to tumor bank.

INK CODE: Black - Gerota's fascia, overlying the tumor.

SECTION CODE: A1, A2, representative section of adrenal gland; A3, ureteral and vascular margins; A4, normal kidney; A5, tumor to ink on Gerota's fascia; A6, tumor in vessel; A7, A8, tumor in renal sinus; A9, tumor to inked additional sections; A10-A22, multiple representative sections of tumor [REDACTED]

(B) PERIAORTIC LYMPH NODE, LEFT - A matted lymph node, 5.8 x 1.8 x 1.0 cm and one discrete lymph node, 1.2 x 1.0 x 0.5 cm. Cut surfaces are unremarkable.

SECTION CODE: B1-B6, larger lymph node, serially sectioned and submitted entirely; B7, smaller lymph node, bisected and submitted entirely [REDACTED]

(C) GASTROINTESTINAL PREAORTIC LYMPH NODES - A 2.0 x 2.0 x 0.3 cm fragment of soft tissue. One lymph node and three irregular nodular areas are identified. Submitted entirely in C. [REDACTED]

(D) SUPRAHILAR LYMPH NODE - A 1.2 x 1.2 x 0.4 cm fragment of soft tissue. Three nodules are identified. The first nodule appears to be a lymph node and is submitted entirely in D1; the other two nodules in D2; possible blood vessel in D3. [REDACTED]

(E) MECKEL'S DIVERTICULUM - A 3.0 x 1.5 cm tubular structure, stapled at one end. One end contains a hard calculus. Cut sections reveal a yellow-black 0.8 x 0.7 x 0.7 cm calculus. Serially sectioned and entirely submitted, E1-E3. [REDACTED]

CLINICAL HISTORY

Source: NCI Genomic Data Commons file 2a3341d7-62bb-496f-9773-cff208367e40 (TCGA-CJ-4904.48AADD82-1ECC-4D20-B34E-1C0F96BAF3F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).